Somatic mutation profile of tumor specimen 0DMUZH from CCDI case PBCALL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.1 years (3,689 days).
Specimen 0DMUZH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 379ac1de-cad9-4ff5-b978-647cce456a90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMUXA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c953d5f-c8eb-4b18-8a5d-940915a05279

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Missense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FSTL5 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 40/1426 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.086); called by muse, mutect2
- OR8U1 | c.20C>T p.T7I | Missense Mutation (SNP) | VAF 463/1274 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 50/1665 reads (3%) | called by muse, mutect2
- SPEN | c.7956C>T p.S2652= | Silent (SNP) | VAF 178/452 reads (39%) | catalogued as rs755358455, COSV101005273; called by muse, varscan2
- DPM3 | c.-32+85G>C | Intron (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
